Somatic mutation profile of tumor specimen 0DFXH4 from CCDI case PBBSRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (64 days).
Specimen 0DFXH4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a2e3178-0e9b-4152-b61d-d069bf360c17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXEZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aad2bb98-5e6a-4f21-b8f1-878c02cbdf7c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INPP5J | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 166/416 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- MTERF4 | c.*876G>A | 3'UTR (SNP) | VAF 248/872 reads (28%) | catalogued as rs777713504; called by muse, mutect2, varscan2
